Surgical pathology report (de-identified scan), TCGA case TCGA-KT-A7W1, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Hartford, specimen TCGA-KT-A7W1-01A (Primary Tumor).

Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

LOCATION:
SUBMITTING MD:
CC:

DIAGNOSIS

BIOPSY AND EXCISION, BRAIN TUMOUR, RIGHT FRONTAL LOBE: ANAPLASTIC ASTROCYTOMA, WHO GRADE III.

Electronically Signed Out

COMMENT

Microscopy shows a diffusely infiltrating highly cellular glial tumour with elongated pleomorphic nuclei with karyofhexis and scattered mitotic figures. Endothelial proliferation and tumour necrosis are not seen. IP stain for GFAP is strongly positive, MIB-1 nuclear proliferative marker shows estimated 5-10% labeling, and IDH 1 is negative.
883331, 88307, 88342 x2

Clinical Diagnosis and History:

Right brain tumor

Tissue(s) Submitted:

- 1: BRAIN TUMOR
- 2: BRAIN TUMOR (PERMANENT) AND STUDY

Gross Description:

Specimen #1 is received fresh for intraoperative consultation labeled brain tumor and consists of seven tan pink soft to rubbery tissues each measuring approximately 0.2 cm in greatest dimension. A representative section is submitted for frozen section microscopy and subsequently forwarded for permanence labeled 1AFS. The remaining tissue is submitted labeled 1B.

Specimen #2 is received fresh labeled brain tumor (permanent) and study and consists of a 1.5 x 1.0 x 0.8 cm aggregate of tan pink soft to rubbery tissue. A portion of the specimen (approximately 170 mg) is submitted for research studies. The remaining tissue is submitted entirely labeled 2A-2B.

Intraoperative Consult Diagnosis

1A/SMDX/FSDX: HIGH GRADE GLIOMA.

*ICD-O-3
Astrocytoma, grade III 9401/3
Site ^{CNS} Brain, supratentorial NOS C71.0
⑧ Brain, frontal lobe C71.1
9/20/13*

Source: NCI Genomic Data Commons file 93e38bc7-25be-4b51-9059-0f39201a257f (TCGA-KT-A7W1.AE187BD1-6528-4D8D-8059-48C1F06B0D4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).